Somatic mutation profile of tumor specimen C3N-04687-02 (aliquot CPT0293640006) from CPTAC case C3N-04687, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.5 years (22,816 days).
Specimen C3N-04687-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8520e5a-429f-4a6e-93ec-051b13ced3c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04687-31 (Blood Derived Normal), aliquot CPT0293690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4574e4e-8c63-4604-ae06-265be23f3f6c

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 16, Silent 4, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF2 | c.1396C>T p.R466* | Nonsense Mutation (SNP) | VAF 124/192 reads (65%) | catalogued as rs74315504, CM941106, COSV58519978; ClinVar: pathogenic; called by muse, varscan2
- CNTN1 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.267); catalogued as COSV61640578; called by muse, mutect2, varscan2
- FKBP9 | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.376); catalogued as rs552745844, COSV54228756; called by muse, mutect2, varscan2
- LAMB1 | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 33/217 reads (15%) | catalogued as rs1369428503, COSV99741114; called by muse, mutect2, varscan2
- MCOLN2 | c.1481T>A p.F494Y | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1280423285, COSV52293943; called by muse, mutect2, varscan2
- OBSCN | c.12016G>A p.G4006S | Missense Mutation (SNP) | VAF 48/327 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as rs535321159; called by muse, mutect2, varscan2
- PITPNM3 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 108/439 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs771713034; called by muse, mutect2, varscan2
- TMEM245 | c.1163A>G p.K388R | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs894507082; called by muse, mutect2, varscan2
- USP43 | c.1841A>G p.N614S | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as rs950565996; called by muse, mutect2, varscan2
- WBP2 | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV52886525; called by muse, mutect2, varscan2
- CEACAM4 | c.590C>A p.T197N | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA3 | c.2803G>A p.V935M | Missense Mutation (SNP) | VAF 110/323 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- MAST4 | c.1663T>G p.S555A (on ENST00000403625 / NM_001164664.2; = p.S366A on NM_015183.3) | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- NME9 | c.443_445del p.G148del (on ENST00000333911 / NM_001349024.2; = p.G87del on NM_178130.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 27/81 reads (33%) | called by mutect2, pindel, varscan2
- NUP133 | c.1246A>T p.T416S | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.517T>G p.L173V | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- SLC24A1 | c.2386G>T p.D796Y | Missense Mutation (SNP) | VAF 132/356 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SNAP91 | c.1357G>C p.A453P | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.23); called by muse, varscan2
- ZNF99 | c.1747C>T p.H583Y | Missense Mutation (SNP) | VAF 69/485 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ITGAL | c.2439T>C p.D813= | Silent (SNP) | VAF 48/203 reads (24%) | catalogued as rs775851189; called by mutect2, varscan2
- TYK2 | c.2712C>T p.G904= | Silent (SNP) | VAF 51/327 reads (16%) | catalogued as rs746948245; called by muse, mutect2, varscan2
- WDFY3 | c.829C>T p.L277= | Silent (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- ZSCAN22 | c.33G>A p.V11= | Silent (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2
